Somatic mutation profile of tumor specimen C3L-01160-01 (aliquot CPT0170600020) from CPTAC case C3L-01160, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.3 years (22,041 days).
Specimen C3L-01160-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9ffc1b7-ff0a-47d5-8159-7f86d7de4422.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01160-31 (Blood Derived Normal), aliquot CPT0167290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92d6f4f3-07cd-4069-9e47-0dbe2a070450

The open-access MAF lists 94 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 20, Nonsense Mutation 9, Intron 4, 5'UTR 3, Splice Region 3, Frame Shift Ins 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 433/953 reads (45%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.9961C>T p.R3321* | Nonsense Mutation (SNP) | VAF 345/792 reads (44%) | catalogued as rs793888512, CM105475, COSV56410587; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 178/583 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 93/316 reads (29%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.3807T>A p.C1269* | Nonsense Mutation (SNP) | VAF 555/974 reads (57%) | catalogued as COSV100271343; called by muse, mutect2, varscan2
- ASPHD1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 65/412 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs370030676; called by muse, mutect2, varscan2
- CD53 | c.18G>C p.L6F | Missense Mutation (SNP) | VAF 107/548 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV54759950; called by muse, mutect2, varscan2
- CDYL2 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 114/678 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as rs62049900, COSV101629539; called by muse, mutect2, varscan2
- CILP2 | c.2334G>A p.W778* | Nonsense Mutation (SNP) | VAF 435/1210 reads (36%) | catalogued as rs1174381528; called by muse, mutect2, varscan2
- EPHA6 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 40/744 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs762397948; called by muse, mutect2
- GPR55 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 197/718 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs766293332, COSV101235720; called by muse, mutect2, varscan2
- ITPR3 | c.2251A>G p.I751V | Missense Mutation (SNP) | VAF 147/701 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV65413683; called by muse, mutect2, varscan2
- NOTCH1 | c.3407G>A p.G1136D | Missense Mutation (SNP) | VAF 174/830 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1394605454, COSV53076903; called by muse, mutect2, varscan2
- OBSCN | c.17386G>A p.V5796I | Missense Mutation (SNP) | VAF 156/589 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs761881774; called by muse, mutect2, varscan2
- OR4C15 | c.883T>A p.S295T (on ENST00000314644; = p.S241T on NM_001001920.2) | Missense Mutation (SNP) | VAF 118/622 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as rs553077311; called by muse, mutect2, varscan2
- OTOG | c.4931C>T p.T1644M | Missense Mutation (SNP) | VAF 184/924 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs781263629; called by muse, mutect2
- PCDH17 | c.2988G>C p.K996N | Missense Mutation (SNP) | VAF 87/507 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.835); catalogued as COSV64977847; called by muse, mutect2, varscan2
- PDZD7 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 126/582 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200664140, COSV64646917; called by muse, varscan2
- PGBD1 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 152/707 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as rs1341479537; called by muse, mutect2, varscan2
- SHROOM2 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 119/546 reads (22%) | catalogued as rs770261260, COSV66607764; called by muse, mutect2, varscan2
- SLC39A12 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 110/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66194540; called by muse, mutect2, varscan2
- SMAD4 | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 96/341 reads (28%) | catalogued as COSV61685105; called by muse, mutect2, varscan2
- SMG5 | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 135/658 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs778890387; called by muse, mutect2, varscan2
- SOX5 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 230/727 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1253562639; called by muse, mutect2, varscan2
- STARD9 | c.8072C>A p.P2691Q | Missense Mutation (SNP) | VAF 110/563 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51915339; called by muse, mutect2, varscan2
- SULF1 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 88/524 reads (17%) | catalogued as rs1563576026, COSV52676256; called by muse, mutect2, varscan2
- TIMP4 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 95/637 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs142733986; called by muse, mutect2, varscan2
- TRPA1 | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV100084133, COSV51569900; called by muse, mutect2
- TRPA1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 107/510 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085491; called by muse, mutect2, varscan2
- TRPA1 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 107/509 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51574441; called by muse, mutect2, varscan2
- TTI1 | c.1999A>G p.I667V | Missense Mutation (SNP) | VAF 167/667 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.137); catalogued as rs780394309; called by muse, mutect2, varscan2
- UBN2 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs747342378; called by muse, mutect2, varscan2
- ABCB7 | c.1721C>T p.S574L (on ENST00000373394 / NM_001271696.3; = p.S575L on NM_004299.6) | Missense Mutation (SNP) | VAF 118/638 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- AC009093.9 | n.208G>A | Splice Region (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- ADCY10 | c.2360A>C p.D787A | Missense Mutation (SNP) | VAF 86/464 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- AKAP8 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 267/718 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATG5 | c.316-1G>C p.X106_splice | Splice Site (SNP) | VAF 47/180 reads (26%) | called by muse, mutect2, varscan2
- ATP2B1 | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 113/478 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CAPN7 | c.191T>G p.V64G | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CC2D2A | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 150/564 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CECR2 | c.1336G>C p.V446L (on ENST00000342247 / NM_001290047.2; = p.V263L on NM_001290046.1) | Missense Mutation (SNP) | VAF 96/519 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- CPNE9 | c.582dup p.T195Hfs*22 | Frame Shift Ins (INS) | VAF 96/508 reads (19%) | called by mutect2, pindel, varscan2
- DGKI | c.1737T>A p.D579E | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.3391A>T p.T1131S | Missense Mutation (SNP) | VAF 137/603 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GBA3 | c.60A>T p.G20= | Splice Region (SNP) | VAF 91/304 reads (30%) | called by muse, mutect2, varscan2
- GCSAML | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 105/587 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUF1 | c.1638C>G p.Y546* | Nonsense Mutation (SNP) | VAF 102/504 reads (20%) | called by muse, mutect2, varscan2
- LONRF3 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 75/379 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MAGEC3 | c.924G>C p.L308F | Missense Mutation (SNP) | VAF 104/522 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.046); called by muse, mutect2
- MAP7D3 | c.1591A>C p.K531Q | Missense Mutation (SNP) | VAF 107/595 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- MARVELD3 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 83/483 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MCM3AP | c.2273G>T p.C758F | Missense Mutation (SNP) | VAF 117/599 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MLIP | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 105/473 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAP1L2 | c.1034C>G p.T345S | Missense Mutation (SNP) | VAF 149/726 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR1L3 | c.860T>G p.F287C | Missense Mutation (SNP) | VAF 102/497 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- OR5J2 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 132/606 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PSD2 | c.1772A>G p.N591S | Missense Mutation (SNP) | VAF 148/619 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SHANK1 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 161/785 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SNCG | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 23/820 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SRBD1 | c.2818G>A p.V940M | Missense Mutation (SNP) | VAF 102/658 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRPK3 | c.1554G>A p.W518* | Nonsense Mutation (SNP) | VAF 96/760 reads (13%) | called by muse, mutect2, varscan2
- TEKT4 | c.740A>C p.K247T | Missense Mutation (SNP) | VAF 140/727 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TMC2 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 142/620 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TTC27 | c.1611T>A p.H537Q | Missense Mutation (SNP) | VAF 105/572 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZNF268 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 81/381 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF521 | c.2182C>A p.Q728K | Missense Mutation (SNP) | VAF 149/595 reads (25%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKFN1 | c.3282C>T p.D1094= (on ENST00000653862; = p.D947= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 302/880 reads (34%) | catalogued as rs996720759; called by muse, mutect2, varscan2
- ASF1B | c.291C>T p.I97= | Silent (SNP) | VAF 130/885 reads (15%) | called by muse, mutect2, varscan2
- CCDC184 | c.151C>T p.L51= | Silent (SNP) | VAF 208/857 reads (24%) | called by muse, mutect2, varscan2
- CSMD1 | c.9525G>A p.K3175= (on ENST00000520002; = p.K3174= on NM_033225.6) | Silent (SNP) | VAF 134/651 reads (21%) | called by muse, mutect2, varscan2
- EPHA6 | c.1038T>A p.A346= | Silent (SNP) | VAF 40/748 reads (5%) | called by muse, mutect2
- FMN2 | c.862C>A p.R288= | Silent (SNP) | VAF 30/1140 reads (3%) | catalogued as COSV100144696; called by muse, mutect2
- GLI3 | c.315C>T p.R105= | Silent (SNP) | VAF 137/599 reads (23%) | catalogued as rs140872736; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGA1 | c.873G>A p.K291= | Silent (SNP) | VAF 116/592 reads (20%) | called by muse, mutect2, varscan2
- KRTAP5-3 | c.570C>T p.C190= | Silent (SNP) | VAF 70/681 reads (10%) | catalogued as rs12808755, COSV68791240; called by muse, varscan2
- LRRK2 | c.3621T>C p.D1207= | Silent (SNP) | VAF 123/429 reads (29%) | called by muse, mutect2, varscan2
- OR4C6 | c.681C>T p.S227= | Silent (SNP) | VAF 89/614 reads (14%) | catalogued as rs753614640, COSV100051722, COSV100051927; called by muse, mutect2, varscan2
- OR52A5 | c.427T>C p.L143= | Silent (SNP) | VAF 126/580 reads (22%) | catalogued as COSV56613991, COSV56614404; called by muse, mutect2, varscan2
- OR5J2 | c.579C>A p.S193= | Silent (SNP) | VAF 132/609 reads (22%) | called by muse, mutect2, varscan2
- OR5M1 | c.273C>A p.T91= | Silent (SNP) | VAF 126/709 reads (18%) | called by muse, mutect2, varscan2
- PRAF2 | c.27A>T p.L9= | Silent (SNP) | VAF 135/646 reads (21%) | called by muse, mutect2, varscan2
- SHISA7 | c.42C>G p.A14= | Silent (SNP) | VAF 145/662 reads (22%) | called by muse, mutect2, varscan2
- SLITRK1 | c.309G>T p.L103= | Silent (SNP) | VAF 164/595 reads (28%) | called by muse, mutect2, varscan2
- TMEM108 | c.396C>T p.R132= | Silent (SNP) | VAF 165/814 reads (20%) | called by muse, mutect2, varscan2
- TRO | c.3741T>A p.A1247= | Silent (SNP) | VAF 221/979 reads (23%) | called by muse, mutect2, varscan2
- ZNF581 | c.78G>T p.R26= | Silent (SNP) | VAF 153/689 reads (22%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7138G>T | Intron (SNP) | VAF 103/469 reads (22%) | called by muse, mutect2, varscan2
- GSTM4 | c.112+21G>C | Intron (SNP) | VAF 71/302 reads (24%) | catalogued as rs778580839; called by muse, mutect2, varscan2
- HAUS7 | c.384+554C>T | Intron (SNP) | VAF 107/440 reads (24%) | catalogued as rs1556983490; called by muse, mutect2, varscan2
- HRH2 | chr5:175685451 ins CATT | 3'Flank (INS) | VAF 119/516 reads (23%) | catalogued as rs1561732144; called by mutect2, varscan2
- KNCN | c.-6G>A | 5'UTR (SNP) | VAF 86/369 reads (23%) | called by muse, mutect2, varscan2
- LILRB5 | c.1630-78_1630-48delinsGTGAGTCCTTTCCTCTCCAGGCCCCCAGGCC | Intron (ONP) | VAF 35/332 reads (11%) | called by pindel, varscan2*
- RPL39 | c.-20T>C | 5'UTR (SNP) | VAF 103/604 reads (17%) | called by muse, mutect2, varscan2
- TAZ | c.-15G>A | 5'UTR (SNP) | VAF 86/416 reads (21%) | catalogued as COSV99186236; called by muse, mutect2, varscan2
